Somatic mutation profile of tumor specimen ALCH-B0FA-TTP1-A (aliquot ALCH-B0FA-TTP1-A-1-0-D-A709-36) from ALCHEMIST case ALCH-B0FA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.6 years (23,218 days).
Specimen ALCH-B0FA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af457d33-9af1-47ee-bcaf-a2359b21dfcd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0FA-NB1-A (Blood Derived Normal), aliquot ALCH-B0FA-NB1-A-1-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ba8dcbd-283f-4151-b238-f57f24031263

The open-access MAF lists 101 somatic variants for this specimen: 75 protein-altering or splice-affecting, 10 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 10, Intron 7, 5'UTR 4, Nonsense Mutation 4, Splice Site 3, In Frame Del 2, RNA 2, 5'Flank 2, 3'UTR 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BEND3 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.953); catalogued as rs782549819, COSV64680996; called by muse, mutect2
- CES5A | c.1427G>A p.G476E (on ENST00000290567 / NM_001143685.2; = p.G426E on NM_145024.3) | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV51869152; called by muse, mutect2
- COL6A1 | c.1776+1G>A p.X592_splice | Splice Site (SNP) | VAF 33/316 reads (10%) | catalogued as CS050379, COSV62612959; called by muse, mutect2
- CPE | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.941); catalogued as rs141250110; called by muse, mutect2, varscan2
- DGKI | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55941877; called by muse, mutect2, varscan2
- ELMO1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767018272, COSV60302807; called by muse, mutect2
- ERBIN | c.2933A>G p.N978S | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs936012621; called by muse, mutect2, varscan2
- LAMA3 | c.1280G>T p.S427I | Missense Mutation (SNP) | VAF 76/544 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as rs1005685820; called by muse, mutect2, varscan2
- LRP2 | c.8600G>T p.S2867I | Missense Mutation (SNP) | VAF 36/468 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1300034758; called by muse, mutect2
- LRRC9 | c.2430T>G p.I810M | Missense Mutation (SNP) | VAF 14/271 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as rs990668758; called by muse, mutect2
- MAP3K14 | c.2054C>A p.T685N | Missense Mutation (SNP) | VAF 58/807 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as rs892790739; called by muse, mutect2
- MARVELD1 | c.340G>C p.G114R | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99579725; called by muse, mutect2, varscan2
- MYADML2 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs1393570167; called by muse, mutect2, varscan2
- NAA30 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 32/339 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1224102042, COSV53648467; called by muse, mutect2
- OR13C3 | c.722T>A p.L241Q | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs781348824; called by muse, mutect2, varscan2
- OR6Q1 | c.626C>A p.A209D | Missense Mutation (SNP) | VAF 32/438 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV100109315; called by muse, mutect2
- OR8H3 | c.167T>G p.L56R | Missense Mutation (SNP) | VAF 20/365 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100538791, COSV57908101, COSV57910433; called by muse, mutect2
- OTX2 | c.69C>A p.D23E | Missense Mutation (SNP) | VAF 32/347 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as rs770855748; called by muse, mutect2
- REP15 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99945357; called by muse, mutect2, varscan2
- RPIA | c.605C>A p.S202* | Nonsense Mutation (SNP) | VAF 15/311 reads (5%) | catalogued as COSV52169296; called by muse, mutect2
- RUNX1T1 | c.740G>A p.R247K (on ENST00000265814 / NM_001198628.1; = p.R220K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV56147648; called by muse, mutect2, varscan2
- TYW1 | c.760G>A p.G254S | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs1039718943; called by muse, mutect2, varscan2
- YY1 | c.1032A>T p.Q344H | Missense Mutation (SNP) | VAF 52/570 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.955); catalogued as COSV51762519; called by muse, mutect2
- ZFP28 | c.2150C>T p.T717I | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.283); catalogued as rs1281834916; called by muse, mutect2, varscan2
- AC069544.2 | c.416T>A p.L139Q | Missense Mutation (SNP) | VAF 55/382 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ALPK2 | c.4964T>G p.F1655C | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.72); called by muse, mutect2
- C2CD4C | c.278_310del p.P93_L103del | In Frame Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- CAND1 | c.3184C>G p.L1062V | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHPT1 | c.646A>G p.T216A | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- CHRNB4 | c.694C>G p.P232A | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL3A1 | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 63/399 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPED1 | c.578_580del p.R193del | In Frame Del (DEL) | VAF 31/275 reads (11%) | called by mutect2, pindel, varscan2
- CRISP3 | c.437del p.S146Tfs*13 (on ENST00000371159 / NM_001368123.1; = p.S128Tfs*13 on NM_006061.4) | Frame Shift Del (DEL) | VAF 21/186 reads (11%) | called by mutect2, pindel, varscan2
- CYC1 | c.609T>A p.A203= | Splice Region (SNP) | VAF 38/151 reads (25%) | called by muse, mutect2, varscan2
- CYP17A1 | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 46/596 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2
- DMD | c.7780C>A p.Q2594K | Missense Mutation (SNP) | VAF 30/550 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.026); called by muse, mutect2
- DTNB | c.419G>T p.C140F | Missense Mutation (SNP) | VAF 19/375 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EIF2AK3 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENTPD1 | c.813+2C>A p.X271_splice | Splice Site (SNP) | VAF 53/254 reads (21%) | called by muse, mutect2, varscan2
- FOXA2 | c.1030C>T p.Q344* (on ENST00000377115 / NM_153675.3; = p.Q350* on NM_021784.5) | Nonsense Mutation (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2
- FZD3 | c.1496G>A p.G499E | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HIC1 | c.707G>A p.C236Y (on ENST00000322941 / NM_001098202.1; = p.C217Y on NM_006497.4) | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- HSD17B13 | c.211-2A>T p.X71_splice | Splice Site (SNP) | VAF 31/170 reads (18%) | called by muse, mutect2, varscan2
- MAGI1 | c.2879G>T p.G960V (on ENST00000402939 / NM_001033057.2; = p.G988V on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/381 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2
- MAP2 | c.1438A>C p.T480P | Missense Mutation (SNP) | VAF 15/368 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.625); called by muse, mutect2
- MEGF10 | c.2693C>A p.A898D | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- MOGS | c.946C>G p.Q316E | Missense Mutation (SNP) | VAF 52/740 reads (7%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.608); called by muse, mutect2
- MYO9A | c.4753G>C p.A1585P | Missense Mutation (SNP) | VAF 13/369 reads (4%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2
- NDUFAB1 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 23/276 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2
- PALD1 | c.1096C>A p.P366T | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2
- PARG | c.2185A>C p.N729H | Missense Mutation (SNP) | VAF 82/490 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PDYN | c.105T>A p.D35E | Missense Mutation (SNP) | VAF 42/544 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2
- PLEKHH3 | c.38G>A p.C13Y | Missense Mutation (SNP) | VAF 40/592 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- PMEL | c.1432T>A p.Y478N | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PNPLA2 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- PSMA8 | c.146A>C p.K49T | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RAB39A | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.038); called by muse, varscan2
- RALGAPA1 | c.2657A>T p.D886V | Missense Mutation (SNP) | VAF 27/348 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.074); called by muse, mutect2
- RFX1 | c.2248C>T p.R750C | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RP1 | c.2581G>T p.E861* | Nonsense Mutation (SNP) | VAF 26/400 reads (7%) | called by muse, mutect2
- SLC24A4 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC2A9 | c.938T>A p.V313D | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SLC35F1 | c.601G>T p.G201* | Nonsense Mutation (SNP) | VAF 19/264 reads (7%) | called by muse, mutect2
- SMTN | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- SPTBN1 | c.34A>T p.I12F | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.045); called by muse, mutect2
- SSH2 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 23/293 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- STXBP5 | c.3223A>G p.R1075G (on ENST00000321680 / NM_001127715.2; = p.R1039G on NM_139244.4) | Missense Mutation (SNP) | VAF 77/359 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TGM6 | c.1909A>C p.K637Q | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- TTN | c.54573A>T p.R18191S (on ENST00000591111; = p.R10767S on NM_003319.4) | Missense Mutation (SNP) | VAF 66/578 reads (11%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USH2A | c.679A>G p.I227V | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2
- ZNF2 | c.1133G>C p.G378A (on ENST00000611147 / NM_001291605.2; = p.G365A on NM_021088.4) | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF512 | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2
- ZNF573 | c.370C>T p.L124F (on ENST00000536220 / NM_001172692.1; = p.L66F on NM_152360.3) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.081); called by muse, mutect2
- ZNF679 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 53/326 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZSCAN32 | c.590C>A p.T197K (on ENST00000396846; = p.Q175K on NM_001284527.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); called by mutect2, varscan2
- DIO2 | c.513G>A p.A171= | Silent (SNP) | VAF 17/206 reads (8%) | catalogued as rs1466984455, COSV70445089; called by muse, mutect2
- FCGR3B | c.132T>G p.T44= | Silent (SNP) | VAF 56/796 reads (7%) | called by muse, mutect2
- MMS22L | c.3579G>A p.L1193= | Silent (SNP) | VAF 26/376 reads (7%) | catalogued as COSV51527494; called by muse, mutect2
- PLD1 | c.417C>T p.I139= | Silent (SNP) | VAF 32/291 reads (11%) | called by muse, varscan2
- RAPGEF2 | c.4335T>G p.A1445= | Silent (SNP) | VAF 50/461 reads (11%) | called by muse, mutect2, varscan2
- RREB1 | c.4134C>T p.D1378= | Silent (SNP) | VAF 20/193 reads (10%) | catalogued as rs544826052, COSV100619357; called by muse, mutect2
- SLIT1 | c.471G>A p.T157= | Silent (SNP) | VAF 14/306 reads (5%) | catalogued as rs1385522580; called by muse, mutect2
- TBX15 | c.1794C>T p.S598= (on ENST00000369429 / NM_001330677.2; = p.S492= on NM_152380.3) | Silent (SNP) | VAF 25/294 reads (9%) | catalogued as rs940764815; called by muse, mutect2
- UBE3C | c.2064G>A p.E688= | Silent (SNP) | VAF 13/192 reads (7%) | catalogued as rs1421724635; called by muse, mutect2
- ZC3H6 | c.2355C>T p.P785= | Silent (SNP) | VAF 20/318 reads (6%) | called by muse, mutect2
- AC244517.10 | c.36-8714G>T | Intron (SNP) | VAF 66/349 reads (19%) | catalogued as COSV101595515; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500378 del ATTA | 5'Flank (DEL) | VAF 45/208 reads (22%) | catalogued as rs1417886381; called by mutect2, pindel, varscan2
- ARMCX4 | c.1038+2811T>A | Intron (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2, varscan2
- ATAD3B | c.*722A>T | 3'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- CEP290 | c.6136-17A>C | Intron (SNP) | VAF 29/174 reads (17%) | called by muse, mutect2, varscan2
- EFEMP2 | c.367+49G>T | Intron (SNP) | VAF 18/236 reads (8%) | called by muse, mutect2
- GLO1 | c.-20T>C | 5'UTR (SNP) | VAF 27/150 reads (18%) | catalogued as rs770864573; called by muse, mutect2, varscan2
- GULP1 | c.610-1872C>T | Intron (SNP) | VAF 46/460 reads (10%) | called by muse, mutect2
- KRT8P11 | n.1037C>A | RNA (SNP) | VAF 29/257 reads (11%) | called by muse, mutect2, varscan2
- MIR493 | n.73G>A | RNA (SNP) | VAF 22/251 reads (9%) | called by muse, mutect2
- MVB12B | c.-15C>G | 5'UTR (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- NPIPA8 | chr16:18339382 G>A | 5'Flank (SNP) | VAF 29/165 reads (18%) | catalogued as rs771334181; called by muse, mutect2, varscan2
- PPP1CB | c.-50C>T | 5'UTR (SNP) | VAF 51/297 reads (17%) | called by muse, mutect2, varscan2
- RFC1 | c.-42G>A | 5'UTR (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- SH3YL1 | c.291+4702T>C | Intron (SNP) | VAF 34/171 reads (20%) | called by muse, varscan2
- TEKT4 | c.499-545C>T | Intron (SNP) | VAF 15/203 reads (7%) | called by muse, mutect2
